Somatic mutation profile of tumor specimen 0E0ZND from CCDI case PBCVFK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0ZND: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aadaf706-45c9-4fa0-9ba7-1d2ec79dbd66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0ZOJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/856d3390-84c4-4b6d-b662-97d518972172

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'UTR 1, Silent 1, Nonsense Mutation 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 152/743 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BCOR | c.3191del p.S1064Wfs*49 | Frame Shift Del (DEL) | VAF 111/262 reads (42%) | catalogued as COSV60711328; called by mutect2, varscan2
- DNAH9 | c.4030C>T p.R1344* | Nonsense Mutation (SNP) | VAF 43/211 reads (20%) | catalogued as rs760026221; called by muse, mutect2, varscan2
- LIMCH1 | c.739A>G p.K247E | Missense Mutation (SNP) | VAF 147/766 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SETD1A | c.1167G>A p.R389= | Silent (SNP) | VAF 39/195 reads (20%) | called by muse, mutect2, varscan2
- DNASE1L1 | chrX:154412057 G>A | 5'Flank (SNP) | VAF 6/68 reads (9%) | catalogued as rs1465488296; called by muse, mutect2
- MOGS | c.-47C>T | 5'UTR (SNP) | VAF 7/45 reads (16%) | catalogued as rs1267990180; called by muse, mutect2, varscan2
